Somatic mutation profile of tumor specimen MP2PRT-PAVLKT-TMP1-A (aliquot MP2PRT-PAVLKT-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVLKT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (881 days).
Specimen MP2PRT-PAVLKT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 264b712a-f5cc-4587-a1c5-1185b45eb6ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVLKT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVLKT-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94178327-8994-49ca-b4a7-7f17a02d8a73

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Nonsense Mutation 1, Splice Region 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC11 | c.1996G>A p.A666T | Missense Mutation (SNP) | VAF 151/469 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as rs112416246; called by muse, mutect2, varscan2
- GRM8 | c.1907C>T p.T636M | Missense Mutation (SNP) | VAF 18/594 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1245423038; called by muse, mutect2
- NOC2L | c.1363C>T p.R455* | Nonsense Mutation (SNP) | VAF 98/594 reads (16%) | catalogued as rs967128892; called by muse, mutect2, varscan2
- OR4M1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 54/571 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1340499119, COSV60060517; called by muse, mutect2
- PCDHA10 | c.1166C>T p.T389M | Missense Mutation (SNP) | VAF 65/380 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.16); catalogued as rs193920994, COSV56487682; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNNT2 | c.96C>T p.D32= | Splice Region (SNP) | VAF 68/345 reads (20%) | catalogued as rs751728017; ClinVar: likely benign; called by muse, mutect2, varscan2
- USH2A | c.14293G>A p.V4765I | Missense Mutation (SNP) | VAF 33/482 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as rs530395989, COSV56339098; called by muse, mutect2
- HDAC2 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 66/357 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGLV4-69 | chr22:22031466 GCATTCACAC>A | Missense Mutation (DEL) | VAF 31/226 reads (14%) | called by pindel, varscan2*
- RFX8 | c.857T>C p.L286S (on ENST00000646446; = p.L215S on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/601 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- RASGRF1 | c.3600C>T p.I1200= | Silent (SNP) | VAF 72/437 reads (16%) | catalogued as rs1276757322; called by muse, mutect2, varscan2
